Somatic mutation profile of tumor specimen MP2PRT-PARDHZ-TMP1-A (aliquot MP2PRT-PARDHZ-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARDHZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,571 days).
Specimen MP2PRT-PARDHZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7a050d6-d45e-4387-8962-68c285ae5abf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARDHZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARDHZ-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21a6a87f-8882-4521-b6c9-bf73e783758e

The open-access MAF lists 61 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 40, Silent 15, Nonsense Mutation 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730880471; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 118/372 reads (32%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.188); catalogued as COSV64105980; called by muse, mutect2, varscan2
- CLIP3 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 179/468 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53078066; called by muse, mutect2, varscan2
- DOCK5 | c.3794T>C p.L1265P | Missense Mutation (SNP) | VAF 79/241 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1348162221; called by muse, mutect2, varscan2
- FAM83B | c.1685G>A p.G562D | Missense Mutation (SNP) | VAF 150/451 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV60922037; called by muse, mutect2, varscan2
- KCNMB2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs553808917, COSV100843943; called by muse, mutect2, varscan2
- LRRC25 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 176/457 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs769281545, COSV59115315; called by muse, mutect2, varscan2
- OR2F2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 162/494 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs773175092, COSV68832666; called by muse, mutect2, varscan2
- OR2L5 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 139/386 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV62365084; called by muse, mutect2, varscan2
- PARD3B | c.2791C>G p.L931V (on ENST00000406610 / NM_001302769.2; = p.L862V on NM_057177.7) | Missense Mutation (SNP) | VAF 132/366 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100595025; called by muse, mutect2, varscan2
- PRDM16 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 30/720 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs200647136; ClinVar: uncertain significance; called by muse, mutect2
- RFX6 | c.1270C>G p.Q424E | Missense Mutation (SNP) | VAF 131/348 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs1165017367, COSV60588597, COSV60589248; called by muse, mutect2, varscan2
- SELP | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 118/354 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs377248328; called by muse, mutect2, varscan2
- SETD2 | c.1679C>G p.S560* | Nonsense Mutation (SNP) | VAF 99/287 reads (34%) | catalogued as COSV57437029, COSV57442585, COSV57443759; called by muse, mutect2, varscan2
- SLC2A8 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs767054400, COSV100972724; called by muse, mutect2, varscan2
- SNAP91 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV52118664; called by muse, mutect2, varscan2
- TBC1D2 | c.2362G>A p.V788I | Missense Mutation (SNP) | VAF 146/414 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776900208, COSV59787044; called by muse, mutect2, varscan2
- TEK | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs540914328, COSV66235022; called by muse, mutect2, varscan2
- TRPC3 | c.367G>A p.G123S (on ENST00000379645 / NM_001366479.2; = p.G50S on NM_003305.2) | Missense Mutation (SNP) | VAF 176/432 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53374492, COSV99313290; called by muse, mutect2, varscan2
- TTN | c.58996G>A p.E19666K (on ENST00000591111; = p.E12242K on NM_003319.4) | Missense Mutation (SNP) | VAF 123/376 reads (33%) | PolyPhen benign (0.355); catalogued as COSV59961616; called by muse, mutect2, varscan2
- TUBA3D | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 181/494 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs112713797; called by muse, mutect2, varscan2
- UBA2 | c.819G>T p.W273C | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55829976; called by muse, mutect2, varscan2
- VEGFD | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 170/450 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV52911250; called by muse, mutect2, varscan2
- ZFP36 | c.323C>A p.S108* (on ENST00000594442; = p.S102* on NM_003407.5) | Nonsense Mutation (SNP) | VAF 221/620 reads (36%) | catalogued as COSV104373686, COSV99953938; called by muse, mutect2
- ZNF568 | c.1099C>A p.H367N | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1385147758; called by muse, mutect2, varscan2
- ABCC5 | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ADGRG2 | c.2358C>G p.F786L (on ENST00000379869 / NM_001079858.3; = p.F783L on NM_005756.4) | Missense Mutation (SNP) | VAF 118/318 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASPM | c.727dup p.R243Pfs*14 | Frame Shift Ins (INS) | VAF 119/400 reads (30%) | called by mutect2, pindel, varscan2
- CAMSAP3 | c.2016G>C p.Q672H | Missense Mutation (SNP) | VAF 130/461 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- FCRL1 | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 113/359 reads (31%) | called by muse, mutect2, varscan2
- GATAD2B | c.755C>T p.T252I | Missense Mutation (SNP) | VAF 135/371 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GIGYF2 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 119/356 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- HDAC6 | c.684C>G p.F228L | Missense Mutation (SNP) | VAF 169/429 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KIF1B | c.175C>G p.H59D | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- KLF8 | c.735G>C p.Q245H | Missense Mutation (SNP) | VAF 91/317 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPAR4 | c.793T>A p.Y265N | Missense Mutation (SNP) | VAF 183/466 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LTB4R2 | c.227T>A p.L76* (on ENST00000528054; = p.L45* on NM_019839.5) | Nonsense Mutation (SNP) | VAF 261/736 reads (35%) | called by muse, mutect2, varscan2
- MSANTD3 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 174/441 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PARP4 | c.4232C>G p.S1411C | Missense Mutation (SNP) | VAF 181/511 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE3A | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 247/714 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHACTR1 | c.264G>C p.E88D | Missense Mutation (SNP) | VAF 113/318 reads (36%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- RASA2 | c.541dup p.H181Pfs*12 | Frame Shift Ins (INS) | VAF 77/300 reads (26%) | called by mutect2, pindel, varscan2
- SCN3A | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 108/337 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SHPRH | c.3946G>C p.E1316Q (on ENST00000275233 / NM_001042683.3; = p.E1320Q on NM_173082.3) | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZFHX4 | c.833T>C p.L278S | Missense Mutation (SNP) | VAF 146/371 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF185 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 117/347 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- CRH | c.24C>T p.S8= | Silent (SNP) | VAF 14/484 reads (3%) | called by muse, mutect2
- CYP4Z1 | c.1473C>G p.L491= | Silent (SNP) | VAF 123/315 reads (39%) | called by muse, mutect2, varscan2
- H2BC4 | c.357C>T p.V119= | Silent (SNP) | VAF 107/332 reads (32%) | catalogued as rs773685186, COSV58417829; called by muse, mutect2, varscan2
- KRTAP13-2 | c.192C>T p.T64= | Silent (SNP) | VAF 17/575 reads (3%) | called by muse, mutect2
- LRRC1 | c.1131G>C p.L377= | Silent (SNP) | VAF 82/250 reads (33%) | called by muse, mutect2, varscan2
- MAB21L2 | c.270C>T p.D90= | Silent (SNP) | VAF 176/468 reads (38%) | called by muse, mutect2, varscan2
- MSH6 | c.2073C>T p.L691= | Silent (SNP) | VAF 146/452 reads (32%) | catalogued as rs1553413445, COSV99316457; ClinVar: likely benign; called by muse, mutect2, varscan2
- OSBPL6 | c.576A>G p.R192= | Silent (SNP) | VAF 125/328 reads (38%) | called by muse, mutect2, varscan2
- PRR18 | c.561G>C p.R187= | Silent (SNP) | VAF 95/364 reads (26%) | called by muse, mutect2, varscan2
- PXDNL | c.3240G>A p.P1080= | Silent (SNP) | VAF 130/404 reads (32%) | catalogued as COSV62496352; called by muse, mutect2, varscan2
- SSTR4 | c.465G>A p.A155= | Silent (SNP) | VAF 230/601 reads (38%) | called by muse, mutect2, varscan2
- STC1 | c.162C>T p.C54= | Silent (SNP) | VAF 123/335 reads (37%) | catalogued as rs780268680, COSV51687613; called by muse, mutect2, varscan2
- USP16 | c.1899C>T p.I633= | Silent (SNP) | VAF 103/270 reads (38%) | catalogued as rs902949702; called by muse, varscan2
- VWF | c.7668C>G p.V2556= | Silent (SNP) | VAF 127/322 reads (39%) | called by muse, mutect2, varscan2
- ZNF514 | c.798G>C p.G266= | Silent (SNP) | VAF 160/438 reads (37%) | called by muse, mutect2, varscan2
